Somatic mutation profile of tumor specimen ALCH-B40B-TTP1-A (aliquot ALCH-B40B-TTP1-A-1-0-D-A799-36) from ALCHEMIST case ALCH-B40B, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 61.8 years (22,567 days).
Specimen ALCH-B40B-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6520334f-2fe1-4b00-b9bd-78864ac41938.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B40B-NB1-A (Blood Derived Normal), aliquot ALCH-B40B-NB1-A-1-0-D-A799-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4ccda57-52e2-4602-8840-9a81279eb61c

The open-access MAF lists 229 somatic variants for this specimen: 151 protein-altering or splice-affecting, 49 silent, 29 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 128, Silent 49, Nonsense Mutation 15, Intron 12, RNA 7, 5'Flank 5, Frame Shift Del 4, Splice Region 3, 3'UTR 2, 5'UTR 2, Splice Site 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.*22C>G | 3'UTR (SNP) | VAF 22/137 reads (16%) | catalogued as rs104894362, CM070970, COSV55666258, COSV56095155; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 91/485 reads (19%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAD2 | c.1618C>A p.L540M (on ENST00000315906 / NM_001145400.2; = p.L622M on NM_139174.4) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1451799950; called by muse, mutect2, varscan2
- ADAM17 | c.1582G>C p.E528Q | Missense Mutation (SNP) | VAF 47/397 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.065); catalogued as COSV60400904; called by muse, mutect2, varscan2
- ADCK2 | c.629G>T p.C210F | Missense Mutation (SNP) | VAF 35/293 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99301704; called by muse, mutect2, varscan2
- ALDH18A1 | c.1393G>C p.E465Q | Missense Mutation (SNP) | VAF 148/820 reads (18%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.719); catalogued as rs757876226; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- AOAH | c.1368C>T p.V456= | Splice Region (SNP) | VAF 95/731 reads (13%) | catalogued as COSV51747125; called by muse, mutect2, varscan2
- APOB | c.8251G>T p.E2751* | Nonsense Mutation (SNP) | VAF 136/791 reads (17%) | catalogued as rs201985284, COSV51942366; called by muse, mutect2, varscan2
- ARHGAP39 | c.1667A>T p.Q556L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.081); catalogued as COSV52776047; called by muse, mutect2, varscan2
- BCHE | c.1311C>A p.F437L | Missense Mutation (SNP) | VAF 148/675 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0.011); catalogued as rs1010031255; called by muse, mutect2, varscan2
- CBARP | c.249G>C p.K83N (on ENST00000382477; = p.K89N on NM_152769.3) | Missense Mutation (SNP) | VAF 20/163 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1227385818; called by muse, mutect2, varscan2
- COL11A1 | c.3475G>A p.G1159S | Missense Mutation (SNP) | VAF 100/670 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV62188945; called by muse, mutect2, varscan2
- COL12A1 | c.8350C>T p.P2784S | Missense Mutation (SNP) | VAF 31/207 reads (15%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.86); catalogued as COSV59401579; called by muse, mutect2, varscan2
- COL22A1 | c.3647G>T p.G1216V | Missense Mutation (SNP) | VAF 88/545 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57323811; called by muse, mutect2, varscan2
- DCD | c.303C>A p.D101E | Missense Mutation (SNP) | VAF 57/437 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.802); catalogued as rs373661792; called by muse, mutect2, varscan2
- DLX5 | c.496G>T p.E166* | Nonsense Mutation (SNP) | VAF 139/963 reads (14%) | catalogued as COSV56031710; called by muse, mutect2, varscan2
- DMD | c.7054G>C p.E2352Q | Missense Mutation (SNP) | VAF 44/255 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.086); catalogued as CM022955; called by muse, mutect2, varscan2
- DUOX1 | c.4538G>A p.R1513Q | Missense Mutation (SNP) | VAF 60/324 reads (19%) | SIFT tolerated (0.46); PolyPhen benign (0.037); catalogued as rs373328305; called by muse, mutect2, varscan2
- EIF5B | c.184C>G p.L62V | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as rs933151229; called by muse, mutect2, varscan2
- ETNPPL | c.928-1G>A p.X310_splice | Splice Site (SNP) | VAF 12/61 reads (20%) | catalogued as COSV56595788, COSV99066211; called by mutect2, varscan2
- FNDC1 | c.5092G>A p.E1698K | Missense Mutation (SNP) | VAF 47/255 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.967); catalogued as COSV51934951; called by muse, mutect2, varscan2
- GAS2L1 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 24/135 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.086); catalogued as rs755368144; called by muse, mutect2, varscan2
- IGHV3-21 | c.60G>C p.E20D | Missense Mutation (SNP) | VAF 50/422 reads (12%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.213); catalogued as rs368327535; called by muse, varscan2
- KNL1 | c.5721C>G p.I1907M (on ENST00000346991 / NM_170589.5; = p.I1881M on NM_144508.5) | Missense Mutation (SNP) | VAF 70/534 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1472445744; called by muse, mutect2, varscan2
- LRRK2 | c.6091A>G p.T2031A | Missense Mutation (SNP) | VAF 72/635 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.18); catalogued as CM070984; called by muse, mutect2, varscan2
- MC2R | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 183/1229 reads (15%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.959); catalogued as COSV59617286; called by muse, mutect2, varscan2
- MOCOS | c.*6del | Frame Shift Del (DEL) | VAF 44/324 reads (14%) | catalogued as rs755830405; called by mutect2, varscan2
- MSI1 | c.344G>A p.G115E | Missense Mutation (SNP) | VAF 43/495 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99981492; called by muse, mutect2
- MTMR7 | c.1009C>T p.H337Y | Missense Mutation (SNP) | VAF 101/628 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99472502; called by muse, mutect2, varscan2
- NPAP1 | c.770C>A p.P257Q | Missense Mutation (SNP) | VAF 20/145 reads (14%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV61506336; called by muse, mutect2, varscan2
- OR10H3 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 79/414 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1347563094, COSV59943991, COSV59944844; called by muse, mutect2, varscan2
- OR8H3 | c.284C>T p.T95M | Missense Mutation (SNP) | VAF 65/507 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs751685926, COSV57909832, COSV57912321; called by muse, mutect2, varscan2
- PARP9 | c.695A>T p.K232M | Missense Mutation (SNP) | VAF 42/465 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.911); catalogued as COSV64451089; called by muse, mutect2
- PKHD1 | c.6938A>G p.N2313S | Missense Mutation (SNP) | VAF 119/785 reads (15%) | SIFT tolerated (0.64); PolyPhen benign (0.007); catalogued as rs1334374415; called by muse, mutect2, varscan2
- PLEC | c.7855G>A p.E2619K (on ENST00000322810 / NM_201380.4; = p.E2509K on NM_000445.5) | Missense Mutation (SNP) | VAF 53/326 reads (16%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.017); catalogued as COSV100511273, COSV59697468; called by muse, mutect2, varscan2
- PPP2R3A | c.1022C>G p.S341* | Nonsense Mutation (SNP) | VAF 12/352 reads (3%) | catalogued as COSV99386855; called by muse, mutect2
- RANBP2 | c.8260C>G p.Q2754E | Missense Mutation (SNP) | VAF 44/380 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs767471375; called by muse, mutect2, varscan2
- RLF | c.4303G>C p.E1435Q | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.796); catalogued as COSV65651714; called by muse, mutect2
- RLF | c.4797G>C p.K1599N | Missense Mutation (SNP) | VAF 56/342 reads (16%) | SIFT tolerated (0.35); PolyPhen benign (0.056); catalogued as COSV101035373; called by muse, mutect2, varscan2
- RSPH1 | c.366G>T p.R122S | Missense Mutation (SNP) | VAF 45/272 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as CS138602; called by muse, mutect2, varscan2
- SCARB2 | c.1430G>A p.R477Q | Missense Mutation (SNP) | VAF 98/718 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.852); catalogued as rs1480481844, COSV53668563; called by muse, mutect2, varscan2
- SEMA6B | c.333C>A p.S111R | Missense Mutation (SNP) | VAF 50/356 reads (14%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.635); catalogued as rs1449734277; called by muse, mutect2, varscan2
- SLC16A1 | c.731C>T p.S244L | Missense Mutation (SNP) | VAF 88/594 reads (15%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV63709599; called by muse, varscan2
- SLC16A7 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 58/434 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV53893699; called by muse, mutect2, varscan2
- SLITRK2 | c.109G>T p.E37* | Nonsense Mutation (SNP) | VAF 66/507 reads (13%) | catalogued as COSV59428417; called by muse, mutect2, varscan2
- SNAPC3 | c.17G>A p.R6Q | Missense Mutation (SNP) | VAF 21/159 reads (13%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs746997280; called by muse, mutect2, varscan2
- SOX3 | c.1219C>T p.P407S | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.986); catalogued as rs768405694; called by muse, mutect2
- SPTBN4 | c.6766G>C p.D2256H | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.006); catalogued as rs1237368416; called by muse, mutect2, varscan2
- SRSF3 | c.268C>A p.R90S | Missense Mutation (SNP) | VAF 49/440 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.931); catalogued as COSV59670606, COSV59671543; called by muse, mutect2, varscan2
- SYT14 | c.1234G>C p.E412Q | Missense Mutation (SNP) | VAF 84/556 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV55052517; called by muse, mutect2, varscan2
- TAF1L | c.1660C>G p.L554V | Missense Mutation (SNP) | VAF 42/278 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV54260347; called by muse, mutect2, varscan2
- TNFAIP8L3 | c.682G>A p.E228K | Missense Mutation (SNP) | VAF 37/176 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as rs1321985754; called by muse, mutect2, varscan2
- TPTE | c.1306G>C p.E436Q (on ENST00000618007 / NM_199261.4; = p.E418Q on NM_199259.4) | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.044); catalogued as rs777978866; called by muse, mutect2
- TRIM39 | c.557T>A p.V186E | Missense Mutation (SNP) | VAF 44/262 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.339); catalogued as rs551694859; called by mutect2, varscan2
- TRIM43 | c.355C>G p.Q119E | Missense Mutation (SNP) | VAF 53/378 reads (14%) | SIFT tolerated (0.16); PolyPhen benign (0.407); catalogued as COSV55527999; called by muse, mutect2, varscan2
- USP44 | c.1135A>G p.I379V | Missense Mutation (SNP) | VAF 40/233 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.062); catalogued as rs1192684162; called by muse, mutect2, varscan2
- WWC3 | c.968C>A p.T323K | Missense Mutation (SNP) | VAF 23/154 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); catalogued as COSV66502165; called by muse, varscan2
- ZFHX4 | c.10182C>A p.Y3394* | Nonsense Mutation (SNP) | VAF 46/253 reads (18%) | catalogued as COSV99257134; called by muse, mutect2, varscan2
- ZNF469 | c.11687C>T p.T3896M (on ENST00000437464; = p.T3924M on NM_001367624.2) | Missense Mutation (SNP) | VAF 87/375 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139259830; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ZNF689 | c.256G>C p.D86H | Missense Mutation (SNP) | VAF 37/330 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54909974; called by muse, varscan2
- ABCC5 | c.1996G>C p.D666H | Missense Mutation (SNP) | VAF 62/704 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- ABHD12B | c.864T>A p.N288K (on ENST00000337334 / NM_001206673.2; = p.N211K on NM_181533.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 24/252 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.833); called by muse, mutect2
- AC073610.2 | c.533C>T p.S178F | Missense Mutation (SNP) | VAF 183/1194 reads (15%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- ADGB | c.3979T>C p.S1327P | Missense Mutation (SNP) | VAF 25/138 reads (18%) | SIFT tolerated (0.35); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- AGRP | c.328T>G p.C110G | Missense Mutation (SNP) | VAF 80/502 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ALMS1 | c.6592G>A p.V2198I | Missense Mutation (SNP) | VAF 25/184 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ANKRD62 | c.91G>T p.G31W | Missense Mutation (SNP) | VAF 100/678 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.368); called by mutect2, varscan2
- ASB18 | c.204A>G p.L68= | Splice Region (SNP) | VAF 45/244 reads (18%) | called by muse, mutect2, varscan2
- ASPH | c.340A>G p.T114A | Missense Mutation (SNP) | VAF 98/729 reads (13%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- BAHCC1 | c.4223G>T p.R1408L | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- BEST3 | c.1657T>A p.S553T | Missense Mutation (SNP) | VAF 50/304 reads (16%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC170 | c.775G>T p.D259Y | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- CEMIP2 | c.3434C>T p.S1145L | Missense Mutation (SNP) | VAF 30/292 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- CER1 | c.264G>C p.K88N | Missense Mutation (SNP) | VAF 73/588 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CFH | c.704A>C p.Y235S | Missense Mutation (SNP) | VAF 48/356 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- CNGA2 | c.70A>C p.I24L | Missense Mutation (SNP) | VAF 60/421 reads (14%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL4A2 | c.1849G>C p.E617Q | Missense Mutation (SNP) | VAF 66/381 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.282); called by muse, mutect2, varscan2
- CPAMD8 | c.1534C>T p.Q512* (on ENST00000651564; = p.Q465* on NM_015692.5) | Nonsense Mutation (SNP) | VAF 20/130 reads (15%) | called by muse, mutect2
- CSPG4 | c.2810T>C p.M937T | Missense Mutation (SNP) | VAF 43/256 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CWF19L2 | c.746G>A p.R249K | Missense Mutation (SNP) | VAF 33/211 reads (16%) | SIFT deleterious (0.04); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- CYP2A6 | c.1255G>C p.E419Q | Missense Mutation (SNP) | VAF 145/840 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- DISP3 | c.808C>G p.H270D | Missense Mutation (SNP) | VAF 6/73 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.197); called by muse, mutect2
- DLG1 | c.1758C>A p.V586= | Splice Region (SNP) | VAF 39/385 reads (10%) | called by muse, mutect2, varscan2
- DMD | c.381C>G p.I127M | Missense Mutation (SNP) | VAF 72/529 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.566); called by muse, mutect2, varscan2
- EGFR | c.3263_3264delinsG p.P1088Rfs*6 | Frame Shift Del (DEL) | VAF 43/309 reads (14%) | called by pindel, varscan2*
- ELP2 | c.984G>A p.W328* | Nonsense Mutation (SNP) | VAF 82/601 reads (14%) | called by muse, mutect2, varscan2
- EPHA3 | c.1991G>T p.R664M | Missense Mutation (SNP) | VAF 53/544 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FANCM | c.2483C>T p.S828L | Missense Mutation (SNP) | VAF 17/139 reads (12%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FLYWCH1 | c.548C>T p.A183V (on ENST00000253928 / NM_001308068.2; = p.A182V on NM_020912.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 74/436 reads (17%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FPR2 | c.106A>G p.T36A | Missense Mutation (SNP) | VAF 56/390 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.166); called by muse, mutect2, varscan2
- GIMD1 | c.54G>C p.Q18H | Missense Mutation (SNP) | VAF 8/187 reads (4%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.698); called by muse, mutect2
- GLG1 | c.838G>T p.E280* | Nonsense Mutation (SNP) | VAF 79/419 reads (19%) | called by muse, mutect2, varscan2
- GSG1L2 | c.536T>A p.M179K | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- H2BW1 | c.247A>G p.T83A | Missense Mutation (SNP) | VAF 57/501 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- HMCN2 | c.11592G>A p.M3864I | Missense Mutation (SNP) | VAF 31/231 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV3-15 | c.297G>T p.Q99H | Missense Mutation (SNP) | VAF 262/2185 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.255); called by muse, varscan2
- IGKV3-20 | c.85G>T p.G29C | Missense Mutation (SNP) | VAF 130/938 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.608); called by muse, varscan2
- INSC | c.612G>C p.E204D | Missense Mutation (SNP) | VAF 55/309 reads (18%) | SIFT tolerated (0.25); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- JCAD | c.2807G>A p.R936H | Missense Mutation (SNP) | VAF 50/401 reads (12%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- LAMA4 | c.5189G>C p.R1730T (on ENST00000230538 / NM_001105206.3; = p.R1723T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 137/777 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- LAMP2 | c.808G>T p.A270S | Missense Mutation (SNP) | VAF 79/556 reads (14%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- LRRC7 | c.2256A>C p.K752N (on ENST00000651989 / NM_001370785.2; = p.K719N on NM_001330635.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 45/293 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.266); called by muse, mutect2, varscan2
- MAU2 | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- MOCS3 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 80/521 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- MPPED1 | c.110G>C p.R37P | Missense Mutation (SNP) | VAF 49/354 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- MTMR11 | c.1364C>G p.S455C (on ENST00000439741 / NM_001145862.2; = p.S383C on NM_181873.3) | Missense Mutation (SNP) | VAF 23/177 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- NEXMIF | c.2869delinsTA p.Q957* | Nonsense Mutation (INS) | VAF 53/526 reads (10%) | called by pindel, varscan2*
- OR2M2 | c.380G>T p.C127F | Missense Mutation (SNP) | VAF 72/381 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR6K6 | c.907G>T p.V303F (on ENST00000368144; = p.V279F on NM_001005184.1) | Missense Mutation (SNP) | VAF 46/399 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- OR8D4 | c.329C>G p.S110C | Missense Mutation (SNP) | VAF 74/474 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.894); called by muse, varscan2
- OR8D4 | c.368A>T p.Y123F | Missense Mutation (SNP) | VAF 35/252 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, varscan2
- PAPOLB | c.1637G>A p.G546D | Missense Mutation (SNP) | VAF 44/405 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- PLCH2 | c.1847A>C p.Q616P | Missense Mutation (SNP) | VAF 48/238 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- PLEC | c.7243G>A p.E2415K (on ENST00000322810 / NM_201380.4; = p.E2305K on NM_000445.5) | Missense Mutation (SNP) | VAF 81/455 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- PLEC | c.4248C>G p.I1416M (on ENST00000322810 / NM_201380.4; = p.I1306M on NM_000445.5) | Missense Mutation (SNP) | VAF 88/576 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- PLEKHS1 | c.108G>C p.W36C (on ENST00000369310 / NM_182601.1; = p.W42C on NM_024889.5) | Missense Mutation (SNP) | VAF 34/190 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PLEKHS1 | c.147G>C p.K49N (on ENST00000369310 / NM_182601.1; = p.K55N on NM_024889.5) | Missense Mutation (SNP) | VAF 27/182 reads (15%) | SIFT tolerated (0.63); PolyPhen benign (0.068); called by muse, mutect2
- PLXNB3 | c.4523G>T p.R1508L | Missense Mutation (SNP) | VAF 47/305 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PRKAB1 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 107/816 reads (13%) | SIFT tolerated (0.42); PolyPhen benign (0.037); called by muse, varscan2
- RASAL2 | c.1673C>G p.S558* | Nonsense Mutation (SNP) | VAF 19/752 reads (3%) | called by muse, mutect2
- RNF19B | c.1431G>T p.K477N | Missense Mutation (SNP) | VAF 24/181 reads (13%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- ROBO1 | c.4817C>T p.S1606L | Missense Mutation (SNP) | VAF 45/324 reads (14%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.297); called by muse, mutect2, varscan2
- RPGRIP1 | c.2321A>C p.Y774S | Missense Mutation (SNP) | VAF 61/273 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SHARPIN | c.463G>A p.G155S | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC16A1 | c.659C>G p.S220C | Missense Mutation (SNP) | VAF 66/525 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, varscan2
- SLC22A12 | c.1504G>C p.G502R | Missense Mutation (SNP) | VAF 145/866 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SLC22A18AS | c.482del p.R161Pfs*7 | Frame Shift Del (DEL) | VAF 67/435 reads (15%) | called by mutect2, pindel, varscan2
- SLC26A7 | c.578C>A p.S193* | Nonsense Mutation (SNP) | VAF 52/328 reads (16%) | called by muse, mutect2, varscan2
- SLC27A2 | c.1006G>C p.A336P | Missense Mutation (SNP) | VAF 16/148 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- SLC7A2 | c.450G>C p.L150F (on ENST00000494857 / NM_001370338.1; = p.L190F on NM_003046.6) | Missense Mutation (SNP) | VAF 27/289 reads (9%) | SIFT tolerated (0.59); PolyPhen benign (0.001); called by muse, mutect2
- SLCO1A2 | c.473G>C p.W158S | Missense Mutation (SNP) | VAF 24/148 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SPDYC | c.716C>G p.S239C | Missense Mutation (SNP) | VAF 42/309 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- SPSB3 | c.410C>T p.A137V | Missense Mutation (SNP) | VAF 30/223 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SPTAN1 | c.376G>A p.E126K | Missense Mutation (SNP) | VAF 102/682 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- SREBF2 | c.1634A>G p.N545S | Missense Mutation (SNP) | VAF 122/825 reads (15%) | SIFT tolerated (0.22); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- SSH3 | c.1493C>T p.P498L | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- STAT1 | c.1719G>A p.W573* | Nonsense Mutation (SNP) | VAF 124/929 reads (13%) | called by muse, mutect2, varscan2
- STXBP6 | c.247G>T p.E83* | Nonsense Mutation (SNP) | VAF 111/438 reads (25%) | called by muse, mutect2, varscan2
- SYN1 | c.1744C>T p.P582S | Missense Mutation (SNP) | VAF 11/125 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.027); called by muse, mutect2
- TBX22 | c.1451G>T p.R484I | Missense Mutation (SNP) | VAF 79/464 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TRUB1 | c.865G>C p.A289P | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2, varscan2
- TSPOAP1 | c.366del p.N123Ifs*5 | Frame Shift Del (DEL) | VAF 42/307 reads (14%) | called by mutect2, pindel, varscan2
- TTLL9 | c.711T>A p.F237L | Missense Mutation (SNP) | VAF 48/337 reads (14%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP34 | c.4694C>G p.S1565* | Nonsense Mutation (SNP) | VAF 141/936 reads (15%) | called by muse, mutect2, varscan2
- WNT11 | c.169C>G p.Q57E | Missense Mutation (SNP) | VAF 104/748 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); called by muse, mutect2, varscan2
- WWP1 | c.275C>A p.A92D | Missense Mutation (SNP) | VAF 23/191 reads (12%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.821); called by muse, mutect2, varscan2
- XPO1 | c.2863G>C p.E955Q | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT tolerated (0.41); PolyPhen benign (0.003); called by muse, mutect2
- ZDBF2 | c.2211C>G p.D737E | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- ZFP69B | c.1321C>G p.H441D | Missense Mutation (SNP) | VAF 38/236 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF253 | c.191C>T p.T64I | Missense Mutation (SNP) | VAF 30/356 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.007); called by muse, mutect2
- ZNF630 | c.1780C>A p.P594T | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZXDB | c.496G>T p.A166S | Missense Mutation (SNP) | VAF 23/272 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0); called by muse, mutect2
- ABCA1 | c.5664G>A p.L1888= | Silent (SNP) | VAF 65/509 reads (13%) | called by muse, mutect2, varscan2
- ABHD4 | c.168C>T p.I56= | Silent (SNP) | VAF 206/734 reads (28%) | catalogued as rs150297491; called by muse, mutect2, varscan2
- ADAMTS17 | c.1953G>A p.R651= | Silent (SNP) | VAF 103/624 reads (17%) | called by muse, mutect2, varscan2
- ATP8B4 | c.2658G>T p.V886= | Silent (SNP) | VAF 23/152 reads (15%) | called by muse, mutect2, varscan2
- ATR | c.4464A>T p.A1488= | Silent (SNP) | VAF 139/406 reads (34%) | called by muse, mutect2, varscan2
- BCL2L15 | c.99C>T p.N33= | Silent (SNP) | VAF 86/481 reads (18%) | catalogued as rs1447876418, COSV63642880; called by muse, mutect2, varscan2
- BTK | c.1785G>A p.K595= | Silent (SNP) | VAF 107/694 reads (15%) | catalogued as COSV100437963; called by muse, mutect2, varscan2
- CDH10 | c.60C>T p.C20= | Silent (SNP) | VAF 78/552 reads (14%) | catalogued as COSV52570087; called by muse, mutect2, varscan2
- CNTNAP2 | c.216G>T p.G72= | Silent (SNP) | VAF 84/581 reads (14%) | called by muse, mutect2, varscan2
- DMBT1 | c.1437C>T p.I479= | Silent (SNP) | VAF 80/549 reads (15%) | called by muse, mutect2, varscan2
- DNAJC10 | c.2053C>T p.L685= | Silent (SNP) | VAF 33/192 reads (17%) | catalogued as COSV51146687, COSV51149827; called by muse, mutect2, varscan2
- E2F7 | c.2481G>A p.V827= | Silent (SNP) | VAF 112/648 reads (17%) | called by muse, mutect2, varscan2
- EFR3B | c.1368G>A p.L456= | Silent (SNP) | VAF 56/413 reads (14%) | called by muse, mutect2, varscan2
- ELAVL3 | c.807C>A p.G269= | Silent (SNP) | VAF 11/77 reads (14%) | catalogued as COSV52954505; called by muse, mutect2, varscan2
- ETV6 | c.810C>T p.P270= | Silent (SNP) | VAF 42/268 reads (16%) | catalogued as rs780112160; called by muse, mutect2, varscan2
- FAM149B1 | c.1563C>A p.P521= | Silent (SNP) | VAF 94/606 reads (16%) | catalogued as COSV54349559; called by muse, mutect2, varscan2
- FARSA | c.1044C>T p.V348= | Silent (SNP) | VAF 11/47 reads (23%) | called by muse, mutect2, varscan2
- GNPTAB | c.927C>T p.I309= | Silent (SNP) | VAF 98/814 reads (12%) | called by muse, mutect2, varscan2
- GPR101 | c.120C>A p.I40= | Silent (SNP) | VAF 22/236 reads (9%) | called by muse, mutect2
- GRIA3 | c.1590C>A p.I530= | Silent (SNP) | VAF 29/204 reads (14%) | called by muse, mutect2, varscan2
- MAN2A1 | c.1839A>G p.T613= | Silent (SNP) | VAF 22/194 reads (11%) | called by muse, mutect2, varscan2
- MAPK4 | c.1017G>A p.L339= | Silent (SNP) | VAF 76/615 reads (12%) | called by muse, mutect2, varscan2
- MMP25 | c.780C>G p.G260= | Silent (SNP) | VAF 18/114 reads (16%) | catalogued as COSV60678599; called by muse, mutect2, varscan2
- MMRN1 | c.1278A>C p.I426= | Silent (SNP) | VAF 29/246 reads (12%) | called by muse, mutect2, varscan2
- MORC4 | c.870G>A p.V290= | Silent (SNP) | VAF 62/456 reads (14%) | called by muse, mutect2, varscan2
- NCOA1 | c.1413C>T p.L471= | Silent (SNP) | VAF 42/357 reads (12%) | called by muse, mutect2, varscan2
- NRP1 | c.468A>T p.G156= | Silent (SNP) | VAF 51/349 reads (15%) | called by muse, mutect2, varscan2
- OR10G8 | c.222C>T p.V74= | Silent (SNP) | VAF 85/647 reads (13%) | catalogued as COSV70909471; called by muse, mutect2, varscan2
- OR7D4 | c.111C>A p.V37= | Silent (SNP) | VAF 56/571 reads (10%) | called by muse, mutect2
- PAGE4 | c.306A>G p.P102= | Silent (SNP) | VAF 23/230 reads (10%) | catalogued as rs782602468; called by muse, mutect2, varscan2
- PCNX2 | c.1188G>C p.L396= | Silent (SNP) | VAF 38/238 reads (16%) | called by muse, mutect2, varscan2
- PDE1A | c.357G>T p.R119= | Silent (SNP) | VAF 39/191 reads (20%) | catalogued as COSV59523647; called by muse, mutect2, varscan2
- PLXNB3 | c.3444C>A p.P1148= | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2, varscan2
- POFUT1 | c.756G>A p.L252= | Silent (SNP) | VAF 12/332 reads (4%) | called by muse, mutect2
- RIMKLB | c.328C>T p.L110= | Silent (SNP) | VAF 30/239 reads (13%) | called by muse, mutect2, varscan2
- RYR3 | c.5145G>A p.G1715= | Silent (SNP) | VAF 60/349 reads (17%) | called by muse, mutect2, varscan2
- SASH3 | c.633C>A p.G211= | Silent (SNP) | VAF 47/310 reads (15%) | catalogued as rs898599826; called by muse, mutect2, varscan2
- SETD3 | c.759G>C p.T253= | Silent (SNP) | VAF 47/407 reads (12%) | called by muse, mutect2, varscan2
- SLC1A5 | c.234G>T p.A78= | Silent (SNP) | VAF 81/516 reads (16%) | catalogued as rs751973271, COSV101314789; called by muse, mutect2, varscan2
- SLC4A1 | c.1641C>T p.H547= | Silent (SNP) | VAF 59/423 reads (14%) | called by muse, mutect2, varscan2
- TAFA5 | c.360G>A p.T120= (on ENST00000402357 / NM_001082967.3; = p.T113= on NM_015381.7) | Silent (SNP) | VAF 48/152 reads (32%) | catalogued as rs199726140; called by muse, mutect2, varscan2
- TCFL5 | c.1437G>T p.P479= | Silent (SNP) | VAF 91/591 reads (15%) | catalogued as COSV53895663; called by muse, mutect2, varscan2
- TDRD5 | c.1395A>G p.P465= | Silent (SNP) | VAF 92/650 reads (14%) | called by muse, mutect2, varscan2
- TENM1 | c.1770C>T p.D590= | Silent (SNP) | VAF 71/606 reads (12%) | catalogued as rs781209857, COSV104427749; called by muse, mutect2, varscan2
- TTI2 | c.165C>G p.L55= | Silent (SNP) | VAF 91/826 reads (11%) | catalogued as COSV62453858; called by muse, mutect2, varscan2
- TTK | c.405C>T p.A135= | Silent (SNP) | VAF 35/382 reads (9%) | catalogued as rs1036408059; called by muse, mutect2
- ZNF628 | c.480G>A p.S160= | Silent (SNP) | VAF 28/270 reads (10%) | called by muse, mutect2
- ZNF676 | c.975C>G p.S325= (on ENST00000650058; = p.S293= on NM_001001411.3) | Silent (SNP) | VAF 86/730 reads (12%) | catalogued as COSV101236261; called by muse, mutect2
- ZNF883 | c.897G>A p.Q299= | Silent (SNP) | VAF 48/378 reads (13%) | called by muse, mutect2, varscan2
- AC024940.1 | n.3497C>G | RNA (SNP) | VAF 35/254 reads (14%) | called by muse, mutect2, varscan2
- AC107023.1 | chr12:40445578 G>A | 5'Flank (SNP) | VAF 57/462 reads (12%) | called by muse, mutect2, varscan2
- AL136982.4 | n.145G>C | RNA (SNP) | VAF 78/488 reads (16%) | called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852236 G>A | 3'Flank (SNP) | VAF 48/304 reads (16%) | catalogued as rs369038957; called by muse, mutect2, varscan2
- BICDL1 | c.1308+1785A>G | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- CACNA1A | c.4001+20T>A | Intron (SNP) | VAF 12/412 reads (3%) | called by muse, mutect2
- CXorf38 | c.352-1032G>T | Intron (SNP) | VAF 30/169 reads (18%) | called by muse, mutect2, varscan2
- F8 | chrX:155026790 C>G | 5'Flank (SNP) | VAF 6/14 reads (43%) | catalogued as COSV64270049; called by muse, mutect2, varscan2
- FGF12 | c.414+66662A>C | Intron (SNP) | VAF 176/671 reads (26%) | called by muse, mutect2, varscan2
- FMO6P | n.1673G>A | RNA (SNP) | VAF 47/288 reads (16%) | called by muse, mutect2, varscan2
- H3P12 | chr3:109410164 G>C | 5'Flank (SNP) | VAF 192/770 reads (25%) | catalogued as rs769933333; called by muse, mutect2, varscan2
- HERC2P3 | n.2231+22374T>A | Intron (SNP) | VAF 28/314 reads (9%) | called by muse, mutect2
- IGHD2-2 | chr14:105921256 C>G | 5'Flank (SNP) | VAF 8/209 reads (4%) | called by muse, mutect2
- KIAA1958 | c.1172-26993G>A | Intron (SNP) | VAF 49/371 reads (13%) | called by muse, mutect2, varscan2
- LARS2 | c.*780C>T | 3'UTR (SNP) | VAF 47/241 reads (20%) | called by muse, mutect2, varscan2
- LINC01558 | n.320G>A | RNA (SNP) | VAF 67/425 reads (16%) | catalogued as rs909619552; called by muse, mutect2, varscan2
- MACROD2 | c.859+879G>A | Intron (SNP) | VAF 78/712 reads (11%) | called by muse, mutect2, varscan2
- NDUFA1 | c.-42A>T | 5'UTR (SNP) | VAF 40/292 reads (14%) | catalogued as rs750246311; called by mutect2, varscan2
- NFKBID | c.-81G>T | 5'UTR (SNP) | VAF 65/403 reads (16%) | called by muse, mutect2, varscan2
- OBSCN | c.11659+3389C>T | Intron (SNP) | VAF 154/1237 reads (12%) | called by muse, mutect2, varscan2
- PCK2 | c.29+361C>G | Intron (SNP) | VAF 109/464 reads (23%) | called by muse, mutect2, varscan2
- RCC1 | c.-261-697G>C | Intron (SNP) | VAF 90/597 reads (15%) | catalogued as rs764180198; called by muse, mutect2, varscan2
- REXO1L1P | n.772C>T | RNA (SNP) | VAF 50/1109 reads (5%) | catalogued as rs1383861624; called by muse, mutect2
- REXO1L1P | n.771C>A | RNA (SNP) | VAF 51/1121 reads (5%) | called by muse, mutect2
- RUSF1 | c.1017-108G>C | Intron (SNP) | VAF 31/932 reads (3%) | called by muse, mutect2
- TFAP2A | chr6:10419450 T>C | 5'Flank (SNP) | VAF 29/310 reads (9%) | called by muse, mutect2, varscan2
- TTN | c.10361-5586C>A | Intron (SNP) | VAF 60/315 reads (19%) | catalogued as COSV59940246, COSV60084261; called by muse, mutect2, varscan2
- XIST | n.10811C>A | RNA (SNP) | VAF 55/352 reads (16%) | called by muse, mutect2, varscan2
